Surgical pathology report (de-identified scan), TCGA case TCGA-36-2552, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2552-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

TCGA-36-2552

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

A. Left ovary and tube:

1. High-grade serous carcinoma replacing left ovary.
2. Single microscopic focus of tumor on tubal serosa (? implant ? artifact) (see comment).

B. Omentum: Negative for tumor.

C. Right tube, ovary and uterus (with cervix):

1. High-grade serous carcinoma replacing ovary and focally involving tubal fimbria (see comment).
2. Metastatic high-grade serous carcinoma involving uterine serosa including cul-de-sac.
3. Atrophic endometrium.
4. Adenomyosis and small leiomyoma.
5. Benign cervix.

D. Right pelvic sidewall nodule: Metastatic high-grade serous carcinoma.

E. Peritoneal fluid: High-grade serous carcinoma.

[page 2 of 3]
Final Diagnosis Comment:

The tumor replaces both ovaries and involves the right tubal fimbria. The distribution of the tumour and its bulk in the ovaries favour an ovarian origin with secondary tubal involvement. A microscopic focus of tumour is seen attached to the serosa of the left tube, but I cannot be certain if this is a true implant or artifactual contaminant.

Clinical History as Provided by Submitting Physician:

Corresponding cytology case number:

Complex mass, ascites

Elevated markers

Specimens Received:

A: left tube + ovary

B: omentum

C: right ovary + tube + cervix + uterus

D: right pelvic sidewall nodule

Gross Description:

Received are four containers, each labelled with the patient's name, and demographics.

Container A is labelled LEFT OVARY AND TUBE and consists of the same. The fallopian tube measures 5 cm in length and 0.3 cm in diameter. It is adherent to the tumour mass, measuring 11 cm in greatest dimension. Cross section of the tumour mass shows papillary structure with areas of necrosis.

Representative sections are submitted as follows:

A1 -frozen section block

A2 -fallopian tube

A3-A7 -ovary

Container B is labelled OMENTUM and consists of apron of greater omentum measuring 14 x 10 x 2 cm. Cross section of the omentum shows unremarkable fat. Representative sections are submitted in cassettes B1-B4.

Container C is labelled RIGHT OVARY PLUS TUBE PLUS CERVIX PLUS UTERUS and consists of the same. The right adnexa is submitted separately in the same container. The total weight of the specimen is 210 g. The uterus measures 7 x 3.9 x 2.7 cm. The right adnexa is distorted by tumour mass measuring 13 cm in greatest dimension. A fallopian tube is identified measuring 6 cm in length and 0.6 cm in diameter. A papillary tumour mass is grossly present on the external surface of the

[page 3 of 3]
ovary. The cervix measures 3 cm in length and 3.1 cm in diameter. The mucosa of the exocervix is normal.

The bivalved uterus shows several nabothian-like cysts of the endocervical canal. The endometrium is even with a thickness of 0.1 cm. The myometrium is symmetrical with a maximal thickness of 1.7 cm.

Representative sections are submitted as follows:

C1-C2 -cervix, anterior/posterior
C3 -cul-de-sac
C4-C5 -isthmus, anterior/posterior
C6-C7 -anterior myometrium
C8-C9 -posterior myometrium
C10-C11 -fallopian tube
C12-C16 -ovary

Container D is labelled RIGHT PELVIC SIDEWALL NODE and consists of two fragments of fibrous tissue measuring 3 cm in aggregate. The specimen is submitted in toto in cassettes D1 and D2.

[REDACTED]

Intraoperative Consultation:

FSA/1

Gross Description: Left tube and ovary 11 cm x 7 cm x 4 cm, replaced by friable tissue.

Provisional Diagnosis: (L tube and ovary): High-grade papillary serous carcinoma.

[REDACTED]

[REDACTED] [REDACTED]

Source: NCI Genomic Data Commons file 016e8e96-bb51-4c11-bca0-6640290ef994 (TCGA-36-2552.9504A356-0742-44F1-A218-62B769E64A33.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).